TCGA case TCGA-DB-A4XC — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/33615113-791b-4286-a23a-ad3d1f8d4b09

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 26 years; Vital status: Alive.

Diagnoses (2)
1. Mixed glioma (the primary disease): ICD-O-3 morphology code: 9382/3; ICD-10 code: C71.2; Tissue or organ of origin: Temporal lobe; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 26.6 years (9,705 days); Year of diagnosis: 2010; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 1,421 days (3.9 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Temporal lobe; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 142 days; Days to treatment end: 191 days; Treatment dose: 5,940 cGy; Treatment outcome: Stable Disease; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Nervous system, NOS; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 26.8 years (9,800 days); Days to diagnosis: 95 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 95 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 840 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 1,421 days (3.9 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DB-A4XC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-DB-A4XC-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DB-A4XC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DB-A4XC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligoastrocytoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: Tumor free; Tumor site: Supratentorial, Temporal Lobe; History seizures: Yes; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Family history brain tumor: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Central nervous system; Other malignancy histological type: Astrocytoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,421 days; disease-specific survival: no event (censored), 1,421 days; progression-free interval: no event (censored), 1,421 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DB-A4XC-01A-11D-A26L-01): tumor purity 0.67, ploidy 2, whole-genome doublings 0.
